Somatic mutation profile of tumor specimen TCGA-DD-AACH-01A (aliquot TCGA-DD-AACH-01A-11D-A40R-10) from TCGA case TCGA-DD-AACH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 69.9 years (25,544 days).
Specimen TCGA-DD-AACH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7959feef-2177-467e-a287-45354e2be761.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACH-10A (Blood Derived Normal), aliquot TCGA-DD-AACH-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44f3f9cb-a8be-4c52-a698-e0546f5967a3

The open-access MAF lists 101 somatic variants for this specimen: 79 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 19, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 4, Intron 2, Translation Start Site 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV53324387, COSV99559045; called by muse, mutect2, varscan2
- ADGRE1 | c.2225G>A p.C742Y | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99165212; called by muse, mutect2, varscan2
- ADGRL3 | c.2809A>G p.S937G (on ENST00000506720 / NM_001322402.2; = p.S869G on NM_015236.6) | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101546816; called by muse, mutect2, varscan2
- ADGRL4 | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV100875873; called by muse, mutect2, varscan2
- ADH4 | c.544T>G p.F182V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.342); catalogued as COSV99644138; called by muse, mutect2, varscan2
- AKAP10 | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99855389; called by muse, mutect2, varscan2
- ARHGEF11 | c.4063A>T p.K1355* | Nonsense Mutation (SNP) | VAF 93/126 reads (74%) | catalogued as COSV100168503; called by muse, mutect2, varscan2
- ATG2B | c.632A>G p.H211R | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV100737941; called by muse, mutect2, varscan2
- BRWD1 | c.2624A>G p.N875S | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1229488330, COSV100313279, COSV60894759; called by muse, mutect2, varscan2
- CD19 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV100218100, COSV61188826; called by muse, mutect2, varscan2
- CELA1 | c.687C>A p.S229R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs778999971, COSV53328860, COSV99530060; called by muse, mutect2, varscan2
- CENPA | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.238); catalogued as COSV99273180; called by muse, mutect2, varscan2
- CLCF1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV100425628; called by muse, mutect2, varscan2
- COL3A1 | c.3586T>C p.C1196R | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.721); catalogued as COSV100482882; called by muse, mutect2, varscan2
- CRHBP | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs748736594, COSV99169479; called by muse, mutect2
- CRISPLD1 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 45/146 reads (31%) | catalogued as COSV100081873; called by muse, mutect2, varscan2
- DDX50 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 65/91 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs202146235, COSV101007226; called by muse, mutect2, varscan2
- DNAH11 | c.10264G>A p.G3422R | Missense Mutation (SNP) | VAF 80/159 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764509824, CM105718, COSV100178844; called by muse, mutect2, varscan2
- DNAH5 | c.3370A>T p.S1124C | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99448662; called by muse, mutect2, varscan2
- DUSP5 | c.218C>A p.A73E | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.26); PolyPhen benign (0.392); catalogued as COSV100851874; called by muse, mutect2, varscan2
- EP300 | c.4703A>G p.K1568R | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99608274; called by muse, mutect2, varscan2
- FBXW8 | c.170A>T p.Q57L (on ENST00000309909; = p.Q95L on NM_012174.1) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV99997629; called by muse, mutect2, varscan2
- FGA | c.747G>C p.K249N | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100120330; called by muse, mutect2, varscan2
- FOXE3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100624009; called by muse, mutect2, varscan2
- GGN | c.1706C>A p.A569D | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.429); catalogued as COSV99287429; called by muse, mutect2, varscan2
- GPR158 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140275752, COSV100893626; called by muse, mutect2, varscan2
- HNRNPL | c.1355+1G>A p.X452_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99670230; called by muse, mutect2, varscan2
- HUWE1 | c.4178C>T p.A1393V | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV99471769; called by muse, mutect2, varscan2
- IL22RA1 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99582943; called by muse, mutect2, varscan2
- IPO4 | c.1869+1G>C p.X623_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100268982; called by muse, mutect2, varscan2
- KCNC3 | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1300698491, COSV100979227; called by muse, mutect2, varscan2
- KIF14 | c.4772T>C p.L1591S | Missense Mutation (SNP) | VAF 278/408 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV100950797; called by muse, mutect2, varscan2
- LAIR1 | c.551T>G p.F184C | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100479593; called by muse, mutect2, varscan2
- LEMD3 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 281/706 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100384284; called by muse, mutect2, varscan2
- LMBR1 | c.619+1G>T p.X207_splice | Splice Site (SNP) | VAF 213/417 reads (51%) | catalogued as COSV100626657; called by muse, mutect2, varscan2
- MAGEH1 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs1290189989, COSV100746799; called by muse, mutect2, varscan2
- MAST4 | c.2246A>G p.Y749C (on ENST00000403625 / NM_001164664.2; = p.Y560C on NM_015183.3) | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843875; called by muse, mutect2, varscan2
- MC2R | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs202040791, COSV100562975; called by muse, mutect2, varscan2
- MFSD5 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV100288989; called by muse, mutect2, varscan2
- MUC16 | c.41365C>G p.L13789V | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.937); catalogued as COSV101109848; called by muse, mutect2, varscan2
- MUC6 | c.1726G>T p.D576Y | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101424533; called by muse, varscan2
- NLRP2 | c.950T>A p.L317H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99672200; called by muse, mutect2, varscan2
- NUDT6 | c.668T>C p.M223T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs775987914, COSV99144618; called by muse, mutect2, varscan2
- OR2AG1 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV100264770, COSV56627117; called by muse, mutect2
- OR5T2 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100506905; called by muse, mutect2, varscan2
- PCDHGB5 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs762060556; called by muse, mutect2, varscan2
- PES1 | c.102T>A p.F34L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100073101, COSV58829968; called by muse, mutect2, varscan2
- PNPLA5 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53376194, COSV99336599; called by muse, mutect2, varscan2
- POLD1 | c.3221G>A p.R1074Q | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs541931950, COSV99569926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POSTN | c.1517A>G p.D506G | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs748518149, COSV65713593; called by muse, mutect2, varscan2
- PTPRB | c.3796C>G p.L1266V | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.158); catalogued as COSV99715640, COSV99717087; called by muse, mutect2, varscan2
- RIPOR1 | c.949G>A p.E317K (on ENST00000379312 / NM_001193522.2; = p.E313K on NM_024519.4) | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99242982; called by muse, mutect2, varscan2
- RPL11 | c.253G>T p.G85C (on ENST00000374550 / NM_001199802.1; = p.G86C on NM_000975.5) | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100999664; called by muse, mutect2, varscan2
- RPUSD4 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV100028673; called by muse, mutect2, varscan2
- RYR2 | c.14016G>A p.M4672I | Missense Mutation (SNP) | VAF 183/235 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100768330, COSV63721946; called by muse, mutect2, varscan2
- SEC11C | c.300A>T p.E100D | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as COSV100230996; called by muse, mutect2, varscan2
- SGSM3 | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as rs773812224, COSV50654874; called by muse, mutect2, varscan2
- SLC25A13 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT tolerated (0.6); PolyPhen benign (0.092); catalogued as COSV99673487; called by muse, mutect2, varscan2
- SLC25A32 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV52569517, COSV99884388; called by muse, mutect2, varscan2
- SLC2A6 | c.1115C>G p.T372S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as COSV99390235; called by muse, mutect2, varscan2
- SLCO5A1 | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV99479804; called by muse, mutect2, varscan2
- SPTBN5 | c.3704A>T p.N1235I | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV100311226; called by muse, mutect2, varscan2
- SRRM4 | c.737T>A p.L246H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV99938329; called by muse, mutect2
- TAOK1 | c.2762A>G p.H921R | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV99913894; called by muse, mutect2, varscan2
- TBX20 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 94/172 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101282374, COSV101282423; called by muse, varscan2
- TMC6 | c.310C>A p.R104S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV100130044; called by muse, mutect2, varscan2
- TMEM132D | c.1923+2T>C p.X641_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | catalogued as COSV101242766; called by mutect2, varscan2
- TMPRSS11D | c.376A>G p.N126D | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.671); catalogued as COSV99384623; called by muse, mutect2, varscan2
- TRAPPC6B | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100351082; called by muse, mutect2, varscan2
- TTN | c.55739T>G p.V18580G (on ENST00000591111; = p.V11156G on NM_003319.4) | Missense Mutation (SNP) | VAF 25/142 reads (18%) | PolyPhen benign (0.001); catalogued as COSV100607667; called by muse, mutect2, varscan2
- USF3 | c.4117A>G p.M1373V | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100325112; called by muse, mutect2, varscan2
- ZNF713 | c.120A>T p.Q40H (on ENST00000633730 / NM_001366796.2; = p.Q53H on NM_182633.3) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101289507; called by muse, mutect2, varscan2
- ALB | c.1824_1827del p.L609Nfs*33 | Frame Shift Del (DEL) | VAF 65/160 reads (41%) | called by mutect2, pindel, varscan2
- FANCB | c.1812_1832delinsG p.E605Rfs*46 | Frame Shift Del (DEL) | VAF 97/140 reads (69%) | called by pindel, varscan2*
- FCGBP | c.7755G>T p.Q2585H | Missense Mutation (SNP) | VAF 92/916 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2
- GP1BB | c.546_568del p.R183Vfs*118 | Frame Shift Del (DEL) | VAF 92/691 reads (13%) | called by mutect2, pindel, varscan2
- KRTAP22-1 | c.129_140del p.W43_G46del | In Frame Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- TCEANC | c.159_160del p.Y53* (on ENST00000380600 / NM_001297563.2; = p.Y83* on NM_152634.4) | Frame Shift Del (DEL) | VAF 76/127 reads (60%) | called by mutect2, pindel, varscan2
- TIRAP | c.624_631delinsC p.Q208Hfs*25 (on ENST00000392679 / NM_001318777.1; = p.Q208Hfs*29 on NM_148910.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by pindel, varscan2*
- ATP8B1 | c.198C>G p.V66= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99377187; called by muse, mutect2
- CRACD | c.189C>T p.N63= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV99949090; called by muse, mutect2, varscan2
- CTNNA1 | c.2679G>A p.P893= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as rs1059181, COSV100242566; called by muse, mutect2, varscan2
- DDX58 | c.2772C>A p.S924= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100008034; called by muse, mutect2, varscan2
- EPHA10 | c.2094G>A p.L698= | Silent (SNP) | VAF 78/200 reads (39%) | catalogued as rs1268330134, COSV57625147; called by muse, mutect2, varscan2
- HCRT | c.177C>T p.H59= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99237069; called by muse, mutect2, varscan2
- MUC5B | c.270C>T p.G90= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as rs377569377; called by muse, mutect2, varscan2
- MUC6 | c.1692G>C p.A564= | Silent (SNP) | VAF 40/257 reads (16%) | catalogued as COSV101424534; called by muse, varscan2
- MUCL1 | c.75T>A p.A25= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV100446007; called by muse, mutect2, varscan2
- NMUR2 | c.219C>T p.H73= | Silent (SNP) | VAF 58/180 reads (32%) | catalogued as COSV99676828; called by muse, mutect2, varscan2
- PCDHA13 | c.930C>T p.F310= | Silent (SNP) | VAF 105/174 reads (60%) | catalogued as COSV56498969; called by muse, mutect2, varscan2
- PIKFYVE | c.3936A>G p.T1312= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs767932394, COSV100010484; called by muse, mutect2, varscan2
- PLA2G4E | c.1204C>T p.L402= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV68152461; called by muse, mutect2
- PPP1R17 | c.231A>T p.I77= | Silent (SNP) | VAF 121/214 reads (57%) | catalogued as COSV100566355; called by muse, mutect2, varscan2
- PRICKLE2 | c.1797C>A p.S599= (on ENST00000295902; = p.S543= on NM_198859.4) | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs1265373042, COSV99897092; called by muse, mutect2, varscan2
- R3HDM1 | c.2277T>A p.S759= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as COSV99926102; called by muse, mutect2, varscan2
- SMIM19 | c.78C>G p.T26= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV100646051; called by muse, mutect2, varscan2
- STK39 | c.1048C>T p.L350= | Silent (SNP) | VAF 57/161 reads (35%) | catalogued as COSV100596512; called by muse, mutect2, varscan2
- UEVLD | c.183G>T p.V61= | Silent (SNP) | VAF 118/536 reads (22%) | catalogued as COSV100260870; called by muse, mutect2, varscan2
- MICAL3 | c.-75+43330C>T | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as rs746173175, COSV99261220; called by muse, mutect2, varscan2
- POM121 | chr7:72948998 T>G | 3'Flank (SNP) | VAF 91/115 reads (79%) | catalogued as COSV99988142; called by muse, mutect2, varscan2
- SGCZ | c.40-298582C>T | Intron (SNP) | VAF 25/37 reads (68%) | catalogued as COSV100763087; called by muse, mutect2, varscan2
